Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3349, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3349-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN INFORMATION

Collected:

Received:

Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Left kidney, radical nephrectomy:
Renal cell carcinoma, clear cell type.

Staging sheet #36.

Tumor Characteristics:

1. Histologic type: Renal cell carcinoma, clear cell type.
2. Tumor site: Upper pole.
3. Tumor size: 5.0 x 5.0 x 4.5 cm.
4. Macroscopic extent of tumor: Limited to kidney.
5. Nuclear grade: Fuhrman grade: 2/4.
6. Lymphovascular space invasion: No.
7. Transcapsular invasion: No.
8. Renal vein invasion: No.
9. Venacaval invasion: Not resected.
10. Adrenal gland: Not resected.

Surgical Margin Status:

1. Soft tissue margins: Negative.
2. Ureteral margin: Negative.
3. Vascular Margins: Negative.

Lymph Node Status:

1. None identified with specimen.

Other Significant Findings:

1. pTNM stage: T1bNXMX.

Electronic Signature

COMMENTS:

This case has been reviewed in intradepartmental consultation and as part of the Department's Quality Review Program agreement with the diagnosis.

CLINICAL INFORMATION

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Renal mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Left kidney

SPECIMEN DATA

GROSS DESCRIPTION:

Received in a single container labeled [REDACTED] is a 240 gram left kidney, 13.0 x 8.0 x 7.0 cm in greatest dimension. The capsule is tan-gray glistening displaying an abundant amount of adhered tan-yellow lobular adipose tissue. no adrenal gland is noted with the specimen. Sectioning reveals the capsule strips with ease to display a yellow-brown smooth cortical surface. An upper pole mass is noted below the capsule. The hilar region displays an abundant amount of tan-yellow lobular adipose tissue as well as a portion of ureter, 7.0 cm in length and 0.9 cm in diameter. Bivalving the kidney reveals a pale yellow-brown renal cortex and medulla. The cortex averages 0.8 cm. The specimen displays fat filled calices with slightly blunted pyramids. A well circumscribed tan-orange upper pole mass is noted, 5.0 x 5.0 x 4.5 cm in greatest dimension. This mass occupies approximately 15% of the renal parenchyma. No other lesions are grossly noted. No invasion to the renal pelvis is noted. Samples of the mass have been submitted for genomic in three cassettes. Representative sections submitted in eight cassettes labeled [REDACTED] as follows: renal and vessel margins-1; inked capsule-2; pelvic wall-3; renal mass-4 to 7; normal renal tissue-8.

Source: NCI Genomic Data Commons file 27622795-81b2-4848-b50a-d5e5a6252d95 (TCGA-A3-3349.90AD852E-6D15-4CAC-BF19-5649AED46C19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).